Surgical pathology report (de-identified scan), TCGA case TCGA-DQ-7595, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Of Michigan, specimen TCGA-DQ-7595-01A (Primary Tumor).

Reg#: [REDACTED] Name: [REDACTED] DOB: [REDACTED] Sex: [REDACTED] Age: [REDACTED] User Name: [REDACTED]

ACCN Number	Order Test Code	Order Test Name	Last Updated
ACCN [REDACTED] Collected: [REDACTED]	SPF	SP FINAL REPORT	Updated: [REDACTED]
SP FINAL REPORT Source:			

HISTORY:

Forty-year smoking history. Presents with approximate six-month history of progressively increasing hoarseness. Has had some ongoing left-sided otalgia and dysphagia. Recent biopsy confirmed invasive squamous cell carcinoma. Epiglottitis - permanent.

GROSS:

1. "Epiglottitis" Received in formalin in a small container are five pink-tan mucosal bits, 0.2 x 0.2 to 0.8 x 0.4 cm. Two fragments bisected. Entirely submitted in cassette 1A. (ns)

MICROSCOPIC DIAGNOSIS:

1. Epiglottitis, biopsy: Invasive moderately-differentiated squamous cell carcinoma and carcinoma in-situ.

I, [REDACTED] the signing staff pathologist, have personally examined and interpreted the slides from this case.

[Close]

Source: NCI Genomic Data Commons file fc0efdfa-0a0e-4cf9-9218-cbdf51b11836 (TCGA-DQ-7595.48B4064D-179D-4F4F-AD16-6DF8E87FF016.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).